CCDI case PBBTTG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d21d8a1a-548b-4896-ae6a-8363d5dd0e5b

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 11.9 years (4,349 days).

Biospecimens (3 samples)
- Sample 0DGO9W: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGOAS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DGOBD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
